Surgical pathology report (de-identified scan), TCGA case TCGA-36-1574, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-1574-01A (Primary Tumor).

[page 1 of 2]
CoPath

Anatomical Pathology

Surgical Pathology Consultation Report

TCGA-36-1574

Final Diagnosis:

A. Right ovary biopsy: Invasive serous carcinoma, grade 3/3.

B. Omentum: Extensive replacement by grade 3 serous carcinoma.

C. Left ovary:

1. Ovary showing extensive involvement by grade 3 serous carcinoma.
2. Unremarkable fallopian tube.

D. Right ovary:

1. Ovary extensively involved by grade 3 serous carcinoma with extra-ovarian extension.
2. Adherent appendix and fallopian tube.

E. Peritoneal cytology: High-grade serous carcinoma.

Clinical History as Provided by Submitting Physician:

Ovarian Ca

A. R ovary biopsy

B. Omentum

C. L ovary

D. R ovary

Specimens Received:

A: right ovary bx

B: omentum

C: left ovary

D: right ovary

Gross Description:

Specimen is received in four containers each labelled with the patient's name.

Container "A" is labelled "right ovary biopsy" and consists of a 2.5 x

2.5 x 1.0 cm solid tissue. Frozen section diagnosis: Positive for invasive carcinoma. The specimen is submitted in toto in cassettes "A1" and "A2".

Container "B" is labelled "omentum" and consists of an apron of greater omentum measuring 25.0 x 7.0 x 3.0 cm weighing 179 g. The omentum consists of yellow fat with numerous (at least 16) perforated, partially adherent firm nodules and unilocular cysts measuring 3.5 cm in greatest dimension for the largest one. Sectioning of the nodules demonstrates solid fibrous structures with areas of necrosis and hemorrhage. Cross-section of cysts demonstrates papillary lesion of the inner lining with areas of hemorrhage. Representative sections are submitted as "B1" through "B4".

Container "C" is labelled "left ovary" and consists of a tumour mass measuring 9.5 x 5.0 x 4.1 cm with irregular surface, partially covered with serosa with numerous adhesions with defects. The tumour mass protrudes from the defects from the serosa. Cross-section of the specimen reveals a solid area and multilocular cyst with hemorrhagic content. Representative sections are submitted as "C1" through "C5".

[page 2 of 2]
36-1574

Container "D" is labelled "right ovary" and consists of a tumour mass measuring 13.0 x 13.0 x 5.0 cm weighing 210 g. The external surface is partially covered with serosa roughened with numerous adhesions. It contains numerous defects with the tumour mass protruding from it. Section of this specimen reveals multilocular cysts with a solid area measuring 6.0 x 3.9 x 5.5 cm. The inner lining of the cysts contain numerous papillary lesions protruding from its surface. Representative sections are submitted as "D1" through "D6"

Intraoperative Consultation:

FSA1: GROSS: 2.5 x 2.5 x 1.0 cm solid tissue

PROVISIONAL DIAGNOSIS: Positive for invasive carcinoma

-Favour serous

Source: NCI Genomic Data Commons file 1a504fac-c575-483d-a7d0-42c0e68e3dd7 (TCGA-36-1574.174E0EF6-E8BC-4C43-8253-EE6D3FF9C1CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).